Somatic mutation profile of tumor specimen TCGA-Y8-A8RZ-01A (aliquot TCGA-Y8-A8RZ-01A-11D-A36X-10) from TCGA case TCGA-Y8-A8RZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 55.8 years (20,386 days).
Specimen TCGA-Y8-A8RZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3cae5d2-39b1-4df2-8fd5-51b5a589aecd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Y8-A8RZ-10A (Blood Derived Normal), aliquot TCGA-Y8-A8RZ-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cbea0ef-4a0f-4c4f-be91-5eb3a69e15b6

The open-access MAF lists 70 somatic variants for this specimen: 59 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 48, Silent 11, Nonsense Mutation 4, Splice Site 3, In Frame Del 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.911T>A p.L304Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.388); catalogued as COSV99559572; called by muse, mutect2, varscan2
- AKAP13 | c.1244T>C p.L415P | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as rs1174483357, COSV100774279; called by muse, mutect2, varscan2
- BAP1 | c.1315G>T p.V439L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1559587112, COSV56236229, COSV56237162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C9 | c.67T>C p.Y23H | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.086); catalogued as COSV99662362; called by muse, mutect2, varscan2
- CCT6A | c.1487A>T p.D496V | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99303653; called by muse, mutect2, varscan2
- CDCA8 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as COSV100523700; called by muse, mutect2, varscan2
- CLK2 | c.538T>C p.C180R (on ENST00000368361 / NM_001294339.2; = p.C179R on NM_003993.4) | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100751905; called by muse, mutect2, varscan2
- CNGB1 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV99206055; called by muse, mutect2, varscan2
- CUL3 | c.654+2T>C p.X218_splice | Splice Site (SNP) | VAF 68/113 reads (60%) | catalogued as COSV100024567; called by muse, mutect2, varscan2
- DCTN2 | c.1034A>C p.Q345P (on ENST00000548249 / NM_001261413.2; = p.Q350P on NM_006400.4) | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV100851773; called by muse, mutect2, varscan2
- DENND5B | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100171944; called by muse, mutect2, varscan2
- ELMO1 | c.2138T>C p.I713T | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV100165494; called by muse, mutect2, varscan2
- FOXF2 | c.477C>G p.I159M | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99453399; called by muse, mutect2, varscan2
- FOXL2 | c.923C>G p.A308G | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs922801633, COSV100374730; called by muse, mutect2, varscan2
- GBA2 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100803460; called by muse, mutect2, varscan2
- INTS6 | c.1595T>C p.L532P | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV100247195; called by muse, mutect2, varscan2
- IQUB | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 48/127 reads (38%) | catalogued as rs1370487711, COSV100227270; called by muse, mutect2, varscan2
- KANK3 | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100035609; called by muse, mutect2, varscan2
- KIAA1109 | c.11704T>C p.S3902P | Missense Mutation (SNP) | VAF 99/254 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1267394232, COSV99169611; called by muse, mutect2, varscan2
- LRP5 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99591847, COSV99592458; called by muse, mutect2, varscan2
- MAZ | c.1107+2T>G p.X369_splice | Splice Site (SNP) | VAF 31/108 reads (29%) | catalogued as COSV99361361; called by muse, mutect2, varscan2
- NF1 | c.971G>C p.C324S | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs778890596, COSV100647896; called by muse, mutect2, varscan2
- NOM1 | c.2298G>C p.K766N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99315438, COSV99315937; called by muse, mutect2, varscan2
- NOTCH1 | c.4173C>A p.C1391* | Nonsense Mutation (SNP) | VAF 91/240 reads (38%) | catalogued as COSV53043862; called by muse, varscan2
- NTAN1 | c.438A>T p.E146D | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV99817053; called by muse, varscan2
- NUP214 | c.364T>A p.F122I | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100845366; called by muse, mutect2, varscan2
- OR5D16 | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1363147222, COSV101004093; called by muse, mutect2
- P3H1 | c.808+2T>G p.X270_splice | Splice Site (SNP) | VAF 91/228 reads (40%) | catalogued as COSV52532433, COSV99355457; called by muse, mutect2, varscan2
- PDE1B | c.569G>C p.R190P | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV54492718, COSV99672856; called by muse, mutect2, varscan2
- PIK3C2G | c.3528A>T p.K1176N (on ENST00000676171; = p.K1135N on NM_004570.5) | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99853247; called by muse, mutect2, varscan2
- PLA1A | c.248G>C p.G83A | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.497); catalogued as COSV56330179; called by muse, mutect2, varscan2
- POLE | c.1023T>C p.A341= | Splice Region (SNP) | VAF 22/75 reads (29%) | catalogued as COSV100267756; called by muse, mutect2, varscan2
- PPP6R3 | c.2509C>A p.P837T (on ENST00000393800 / NM_001352375.2; = p.P757T on NM_018312.5) | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99677123; called by muse, mutect2, varscan2
- PRPF40B | c.101T>C p.M34T (on ENST00000380281; = p.M28T on NM_012272.3) | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99980056; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1304A>G p.E435G | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99217220; called by muse, mutect2, varscan2
- RBM15B | c.1555C>G p.R519G | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs1359209355, COSV100082275; called by muse, mutect2, varscan2
- ROBO1 | c.3493C>A p.H1165N | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV101459119, COSV71399337; called by muse, mutect2, varscan2
- SCFD1 | c.1285A>T p.M429L | Missense Mutation (SNP) | VAF 122/330 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV100356501; called by muse, mutect2, varscan2
- SDK1 | c.2391C>A p.H797Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.876); catalogued as COSV101269668; called by muse, mutect2, varscan2
- SI | c.4811G>T p.G1604V | Missense Mutation (SNP) | VAF 91/451 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100016643; called by muse, mutect2, varscan2
- SLC47A1 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99565550; called by muse, mutect2
- SMURF2 | c.2119A>G p.T707A | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV52318350, COSV99300950; called by muse, mutect2, varscan2
- SPEN | c.10862A>G p.Q3621R | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100999052; called by muse, mutect2
- STOX2 | c.886C>G p.P296A | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100408807, COSV100409050; called by muse, mutect2, varscan2
- STXBP5 | c.1586G>A p.R529K | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.787); catalogued as rs1294289426, COSV99470739; called by muse, mutect2, varscan2
- TAF8 | c.804G>C p.E268D | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100881163; called by muse, mutect2, varscan2
- TAF8 | c.805A>T p.N269Y | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100881164; called by muse, mutect2, varscan2
- TCF7L1 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs890539049, COSV99964666; called by muse, mutect2, varscan2
- TMCO1 | c.161C>T p.T54I (on ENST00000612311 / NM_001256164.1; = p.T3I on NM_019026.6) | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.925); catalogued as COSV100903180; called by muse, mutect2, varscan2
- TMEM179B | c.283A>T p.R95* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV99585369; called by muse, mutect2, varscan2
- UBC | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV100299073, COSV100299176; called by muse, mutect2, varscan2
- UVSSA | c.2102C>A p.S701* | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | catalogued as COSV101104569; called by muse, mutect2, varscan2
- ZFR | c.2888G>T p.S963I | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99416333; called by muse, mutect2, varscan2
- ZNF212 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100242445, COSV60024680; called by muse, mutect2, varscan2
- ZNF212 | c.404A>C p.E135A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100242446; called by muse, mutect2, varscan2
- ZNF544 | c.875A>C p.H292P | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV99517189; called by muse, mutect2, varscan2
- CLCN7 | c.953_955del p.F318del | In Frame Del (DEL) | VAF 23/68 reads (34%) | called by mutect2, pindel, varscan2
- GCSAM | c.84_91del p.K28Nfs*11 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- NPR2 | c.2930_2932del p.Y977del | In Frame Del (DEL) | VAF 35/89 reads (39%) | called by mutect2, pindel, varscan2
- AL645922.1 | c.2559A>G p.S853= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as rs1027200708, COSV100191380; called by muse, mutect2, varscan2
- APCDD1 | c.639G>C p.R213= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV100790001; called by muse, mutect2, varscan2
- ARHGAP29 | c.3594C>A p.P1198= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV99558704; called by muse, mutect2, varscan2
- BIRC6 | c.7020C>A p.L2340= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV101428570; called by muse, mutect2, varscan2
- BNIPL | c.171T>C p.D57= | Silent (SNP) | VAF 57/142 reads (40%) | catalogued as COSV99639832; called by muse, mutect2, varscan2
- GDF10 | c.1416G>T p.V472= | Silent (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- MAGEA4 | c.15G>A p.Q5= | Silent (SNP) | VAF 53/92 reads (58%) | catalogued as COSV52341249; called by muse, mutect2, varscan2
- PCSK2 | c.1791C>T p.A597= | Silent (SNP) | VAF 44/99 reads (44%) | catalogued as COSV99360322; called by muse, mutect2, varscan2
- TMED1 | c.408A>G p.G136= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV99284249; called by muse, mutect2, varscan2
- USP29 | c.2157A>G p.K719= | Silent (SNP) | VAF 91/226 reads (40%) | catalogued as rs562830906, COSV99518434; called by muse, mutect2, varscan2
- UTRN | c.3741C>T p.T1247= | Silent (SNP) | VAF 60/152 reads (39%) | catalogued as COSV100840215; called by muse, mutect2, varscan2
